CPTAC case SC-0188 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/746a412d-3054-4c52-8aef-1e81357928f2

Demographics
Sex at birth: male; Vital status: Dead; Days to death: 1,522 days (4.2 years).

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin, NOS; Age at diagnosis: 63.0 years (23,011 days); AJCC staging edition: 8th; AJCC pathologic T: T4b; AJCC pathologic N: NX; AJCC pathologic M: M0; Progression or recurrence: no; Clark level: IV.
   Pathology details: Breslow thickness: 10.5.

Biospecimens (1 sample)
- Sample S-1704-012558: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Frozen; Initial weight: 78 mg; Method of sample procurement: Tumor Resection.
